Somatic mutation profile of tumor specimen TCGA-HZ-7926-01A (aliquot TCGA-HZ-7926-01A-11D-2154-08) from TCGA case TCGA-HZ-7926, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 57.6 years (21,024 days).
Specimen TCGA-HZ-7926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cc5e5e8-fda5-4b3b-a1c8-aef55c88a863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-7926-10A (Blood Derived Normal), aliquot TCGA-HZ-7926-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4471704-e91d-4907-b67a-79e8f5efba44

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 5, Frame Shift Ins 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/135 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATL1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 23/369 reads (6%) | catalogued as rs1442289748, COSV100613099, COSV63296580; called by muse, mutect2
- ATP8A1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV100046197; called by muse, mutect2
- CABP5 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs749204226, COSV99506547, COSV99506564; called by muse, mutect2, varscan2
- CBLIF | c.1226A>G p.H409R | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); catalogued as rs1185755777, COSV99950951; called by muse, mutect2
- CCT3 | c.1135dup p.A379Gfs*2 | Frame Shift Ins (INS) | VAF 48/546 reads (9%) | catalogued as rs1195962947; called by mutect2, pindel
- CEP170B | c.457C>T p.R153W (on ENST00000453495; = p.R83W on NM_015005.3) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765432805, COSV69024664; called by muse, mutect2, varscan2
- CSK | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99583652; called by muse, mutect2
- DDR2 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 52/497 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1442169517, COSV100906564; called by muse, mutect2, varscan2
- DDX4 | c.290C>G p.S97* | Nonsense Mutation (SNP) | VAF 15/454 reads (3%) | catalogued as COSV100737527; called by muse, mutect2
- FLT3 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as rs747273765, COSV99608777; called by muse, mutect2, varscan2
- IP6K2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99583924; called by muse, mutect2
- KCNK13 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 30/520 reads (6%) | catalogued as COSV99965690; called by muse, mutect2
- MAP2 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 129/1136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs146432517; called by muse, mutect2, varscan2
- MATN4 | c.1502G>A p.R501H (on ENST00000372754; = p.R460H on NM_003833.4) | Missense Mutation (SNP) | VAF 40/485 reads (8%) | PolyPhen probably damaging (1); catalogued as rs1157572540, COSV61351910; called by muse, mutect2
- MIA3 | c.5143C>T p.R1715* | Nonsense Mutation (SNP) | VAF 46/396 reads (12%) | catalogued as COSV100485021; called by muse, mutect2, varscan2
- MYO3A | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56323550, COSV56325742; called by muse, mutect2
- OBSL1 | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.982); catalogued as rs745541555, COSV54705824; called by muse, mutect2
- PRDM13 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.037); catalogued as COSV100980494, COSV100980597; called by muse, mutect2
- SHROOM2 | c.4217C>T p.A1406V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1228965812, COSV101098626; called by muse, mutect2
- SLCO4C1 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 94/764 reads (12%) | catalogued as rs202120876; called by muse, mutect2, varscan2
- TP53 | c.902dup p.G302Rfs*4 | Frame Shift Ins (INS) | VAF 60/419 reads (14%) | catalogued as COSV53177081; called by mutect2, pindel, varscan2
- TRMT1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99456994; called by muse, mutect2
- UBQLN3 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61165399; called by muse, mutect2
- UGP2 | c.1406A>G p.N469S | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs749023934, COSV55442634, COSV99708138; called by muse, mutect2
- VCAN | c.7019G>A p.G2340E | Missense Mutation (SNP) | VAF 49/447 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV54106428, COSV99425782; called by muse, mutect2, varscan2
- ZNF75A | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV101556642; called by muse, mutect2
- CDKN2A | c.354dup p.E119* | Frame Shift Ins (INS) | VAF 28/170 reads (16%) | called by mutect2, varscan2
- CLEC4M | c.1164C>A p.I388= | Silent (SNP) | VAF 25/456 reads (5%) | catalogued as COSV99940549; called by muse, mutect2
- CUL9 | c.1437G>A p.P479= | Silent (SNP) | VAF 48/810 reads (6%) | catalogued as rs148427416; called by muse, mutect2
- ERBB4 | c.639T>C p.C213= | Silent (SNP) | VAF 22/463 reads (5%) | catalogued as COSV99623668; called by muse, mutect2
- FOXS1 | c.651G>A p.A217= | Silent (SNP) | VAF 36/329 reads (11%) | catalogued as rs1215500141, COSV54066060; called by muse, mutect2, varscan2
- HELQ | c.2109G>A p.Q703= | Silent (SNP) | VAF 19/362 reads (5%) | catalogued as COSV99787687; called by muse, mutect2
- MTTP | c.555G>C p.V185= | Silent (SNP) | VAF 48/455 reads (11%) | catalogued as COSV99645172; called by muse, mutect2, varscan2
- NLRP3 | c.2253G>A p.L751= | Silent (SNP) | VAF 24/430 reads (6%) | catalogued as COSV100276051; called by muse, mutect2
- OR10K1 | c.405C>T p.L135= | Silent (SNP) | VAF 101/880 reads (11%) | catalogued as COSV56872237, COSV99193559; called by muse, mutect2, varscan2
- PCDHB3 | c.1833G>A p.E611= | Silent (SNP) | VAF 32/807 reads (4%) | catalogued as rs782127732, COSV50630002, COSV99165203; called by muse, mutect2
- SLCO6A1 | c.111A>C p.G37= | Silent (SNP) | VAF 136/1223 reads (11%) | catalogued as COSV101134338, COSV65806059; called by muse, mutect2, varscan2
- ZNF84 | c.2214C>G p.S738= | Silent (SNP) | VAF 18/339 reads (5%) | called by muse, mutect2
- TOMM40L | c.*1G>A | 3'UTR (SNP) | VAF 14/451 reads (3%) | catalogued as rs1208741264, COSV100915675; called by muse, mutect2
